Surgical pathology report (de-identified scan), TCGA case TCGA-HS-A5N9, project TCGA-SARC (Sarcoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HS-A5N9-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	leiomyosarcoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Uterus
Tumour Size (cm)	13
Histology	leiomyosarcoma
Grade/Differentiation	X
Pathological T	N/A
Pathological N	N/A
Clinical M	MP
Histology Comments	Other: Leiomyosarcoma with a focal epithelioid differentiation.

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3

Leiomyosarcoma NOS 8890/3
Site: Uterus NOS C55.9
9/2/11/13

Criteria	2/1/13 W	Yes	No
Prior Malignancy History	OMF Tumor	✓	

Source: NCI Genomic Data Commons file 847f637c-1f07-4ef9-b297-348cfb856430 (TCGA-HS-A5N9.209BE9B7-8426-47FF-9D52-7B339A8049A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).